Somatic mutation profile of tumor specimen TCGA-IB-8126-01A (aliquot TCGA-IB-8126-01A-11D-2396-08) from TCGA case TCGA-IB-8126, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 80.0 years (29,213 days).
Specimen TCGA-IB-8126-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01498203-ff33-4a8d-9d59-7570f1d46a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-8126-10A (Blood Derived Normal), aliquot TCGA-IB-8126-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27633fa9-b405-4847-bd8b-8cc11a0bfef3

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP1 | c.1183C>T p.R395* (on ENST00000393609 / NM_001040118.2; = p.R150* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 34/730 reads (5%) | catalogued as rs887870629, COSV100502108; called by muse, mutect2
- CCDC70 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 49/1124 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV54431297, COSV99665422; called by muse, mutect2
- P2RY8 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 25/659 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV101184153; called by muse, mutect2
- SLC7A3 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV99979750; called by muse, mutect2
- TRPM3 | c.4886A>G p.N1629S (on ENST00000357533 / NM_001366142.2; = p.N1484S on NM_020952.6) | Missense Mutation (SNP) | VAF 114/2710 reads (4%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.046); catalogued as COSV100678306; called by muse, mutect2
- CAMTA1 | c.3238C>T p.L1080= | Silent (SNP) | VAF 25/716 reads (3%) | catalogued as COSV100351937; called by muse, mutect2
- CHAT | c.400C>T p.L134= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as rs1438145765; called by muse, mutect2
- HSP90B1 | c.666C>A p.I222= | Silent (SNP) | VAF 11/317 reads (3%) | called by muse, mutect2
- NUFIP2 | c.1179A>G p.Q393= | Silent (SNP) | VAF 52/720 reads (7%) | catalogued as rs1164491021, COSV99837607; called by muse, mutect2
- SBK1 | c.768G>A p.A256= | Silent (SNP) | VAF 12/205 reads (6%) | catalogued as rs1181840421, COSV100543654; called by muse, mutect2
- SHROOM3 | c.2577C>G p.S859= | Silent (SNP) | VAF 13/411 reads (3%) | called by muse, mutect2
- TNN | c.2370C>T p.D790= | Silent (SNP) | VAF 20/570 reads (4%) | catalogued as COSV99512701; called by muse, mutect2
